Somatic mutation profile of tumor specimen MMRF_1983_1_BM_CD138pos (aliquot MMRF_1983_1_BM_CD138pos_T1_KHS5U_L08853) from MMRF case MMRF_1983, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.5 years (20,987 days).
Specimen MMRF_1983_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ccb3677-7c21-495c-8f7e-3ce18382aa03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1983_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1983_1_PB_Whole_C2_KHS5U_L08788; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37fe158e-ccdb-4c04-9510-200952daac69

The open-access MAF lists 85 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 21, Silent 9, Intron 6, 5'UTR 5, Frame Shift Ins 3, 5'Flank 3, RNA 1, Splice Region 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 21/206 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.963G>T p.R321S | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52629349; called by muse, mutect2, varscan2
- AGMO | c.1273dup p.S425Ffs*10 | Frame Shift Ins (INS) | VAF 92/244 reads (38%) | catalogued as rs1015561522; called by mutect2, pindel, varscan2
- CHRNA1 | c.1306G>A p.E436K (on ENST00000261007 / NM_001039523.3; = p.E411K on NM_000079.4) | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.679); catalogued as rs781158981; called by muse, mutect2, varscan2
- CNGA4 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs202030466; called by muse, mutect2, varscan2
- CNTN6 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs371266935; called by muse, mutect2, varscan2
- CYP4F11 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1339209060; called by muse, mutect2
- FBXW10 | c.3038T>C p.V1013A | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs373632534; called by muse, mutect2, varscan2
- FHDC1 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561578259, COSV52597423; called by muse, mutect2, varscan2
- HBA2 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as CM950607; called by muse, mutect2, varscan2
- IGHV2-70 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs369724963; called by muse, mutect2, varscan2
- LILRB4 | c.1014G>C p.Q338H (on ENST00000391733 / NM_001278428.3; = p.Q337H on NM_001278426.3) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54408627; called by muse, mutect2
- NFASC | c.3290-6C>T | Splice Region (SNP) | VAF 64/385 reads (17%) | catalogued as rs377485532; called by muse, mutect2
- PAPPA2 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs749013840, COSV62772467, COSV62777922; called by muse, mutect2, varscan2
- PCDHA11 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.16); catalogued as COSV56544902; called by muse, mutect2, varscan2
- PRR23B | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs746843659; called by muse, varscan2
- RASAL2 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 132/252 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs769236542; called by muse, mutect2, varscan2
- UNC5B | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs376097676; called by muse, mutect2, varscan2
- XBP1 | c.204C>G p.S68R | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53275108; called by muse, mutect2, varscan2
- XRCC2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs149186933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZMYM3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58737172; called by muse, mutect2, varscan2
- ADAMTS14 | c.1640A>G p.Q547R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- BRWD1 | c.6833A>G p.K2278R | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, varscan2
- BRWD1 | c.6800del p.L2267Rfs*15 | Frame Shift Del (DEL) | VAF 50/124 reads (40%) | called by pindel, varscan2
- CD160 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- DNHD1 | c.10788G>C p.E3596D | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FUS | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- GANC | c.1121A>G p.D374G | Missense Mutation (SNP) | VAF 19/156 reads (12%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GAPT | c.450A>G p.I150M | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IRF7 | c.88T>C p.W30R (on ENST00000397566; = p.W17R on NM_001572.5) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1109 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- METTL7A | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO18A | c.2996T>C p.L999P | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PHIP | c.5278A>G p.K1760E | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); called by muse, mutect2
- SEMG2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SULF2 | c.2546dup p.W850Vfs*33 | Frame Shift Ins (INS) | VAF 34/90 reads (38%) | called by mutect2, pindel, varscan2
- TMEM200C | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ZEB1 | c.1218dup p.I407Yfs*5 | Frame Shift Ins (INS) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- ZNF836 | c.1702A>G p.N568D | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CD19 | c.1293G>A p.Q431= | Silent (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- CHRNA9 | c.1221G>A p.Q407= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- GJA4 | c.903G>A p.A301= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as rs113974864; called by muse, mutect2, varscan2
- KIAA1671 | c.978C>T p.D326= | Silent (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- MAGI2 | c.390T>C p.R130= | Silent (SNP) | VAF 94/201 reads (47%) | called by muse, mutect2, varscan2
- OR10C1 | c.510C>T p.C170= (on ENST00000622521; = p.C168= on NM_013941.3) | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as rs921263489, COSV65823627; called by muse, mutect2, varscan2
- PCDHGA2 | c.2148G>A p.L716= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV53940543; called by muse, mutect2, varscan2
- PTF1A | c.657G>A p.V219= | Silent (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- SNTG1 | c.585A>C p.P195= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs774363405; called by muse, mutect2, varscan2
- AFAP1 | c.-2-44G>A | Intron (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- BARD1 | c.*77T>C | 3'UTR (SNP) | VAF 76/167 reads (46%) | called by muse, mutect2, varscan2
- CNNM2 | c.*1052G>A | 3'UTR (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- DMRTA2 | c.*451A>G | 3'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- DSC2 | c.*5G>A | 3'UTR (SNP) | VAF 54/189 reads (29%) | called by muse, mutect2, varscan2
- ESPNP | n.1422G>A | RNA (SNP) | VAF 5/47 reads (11%) | catalogued as rs1408442437; called by muse, mutect2, varscan2
- FAM110B | c.*24C>T | 3'UTR (SNP) | VAF 21/41 reads (51%) | catalogued as rs754355660; called by muse, mutect2, varscan2
- FUS | c.1169-11A>G | Intron (SNP) | VAF 46/89 reads (52%) | catalogued as rs181859716, COSV54217766; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDAP1 | c.*721A>C | 3'UTR (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- LILRB1 | chr19:54637265 C>T | 3'Flank (SNP) | VAF 4/25 reads (16%) | catalogued as rs568814093, COSV61116972; called by muse, mutect2
- MAP9 | c.*888A>C | 3'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- MC1R | c.-127G>A | 5'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- MEIS1 | c.484-55G>A | Intron (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*2723G>T | 3'UTR (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- NEDD4L | c.1125+61G>A | Intron (SNP) | VAF 22/83 reads (27%) | catalogued as rs934625165; called by muse, mutect2, varscan2
- NUAK2 | c.*883C>T | 3'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- PARVA | c.*2797T>G | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*374T>C | 3'UTR (SNP) | VAF 56/113 reads (50%) | called by muse, mutect2, varscan2
- PLRG1 | c.*1429G>A | 3'UTR (SNP) | VAF 24/85 reads (28%) | catalogued as rs926896269; called by muse, mutect2, varscan2
- PLXNA4 | c.*1283C>T | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- PPP2CA | c.*3289A>G | 3'UTR (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- PTPRO | c.-58C>T | 5'UTR (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- RASSF6 | c.-22A>G | 5'UTR (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- RBP5 | c.*263A>C | 3'UTR (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- RIMBP2 | c.*637C>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs1026441269; called by muse, mutect2, varscan2
- SCART1 | c.*770G>A | 3'UTR (SNP) | VAF 16/40 reads (40%) | catalogued as rs1394368386; called by muse, mutect2, varscan2
- SCFD2 | c.1562-35335T>A | Intron (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62854680 A>G | 5'Flank (SNP) | VAF 10/44 reads (23%) | catalogued as rs1468547609; called by muse, mutect2, varscan2
- SPATS2 | c.25+2475A>G | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.*2148T>G | 3'UTR (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- TENT5C | c.*1886T>G | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- TMEM132E | chr17:34576071 A>C | 5'Flank (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- TMEM19 | c.-147T>G | 5'UTR (SNP) | VAF 85/195 reads (44%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975368 del CAAAACCGAAAAACTGGCGTTTTG | 5'Flank (DEL) | VAF 53/67 reads (79%) | called by mutect2, pindel, varscan2
- TMSB4X | c.*68_*73del | 3'UTR (DEL) | VAF 25/31 reads (81%) | called by mutect2, pindel, varscan2
- VAMP1 | c.-106G>A | 5'UTR (SNP) | VAF 14/89 reads (16%) | catalogued as rs915387940, COSV100655586; called by muse, mutect2, varscan2
- ZAR1L | c.*108C>A | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
